Somatic mutation profile of tumor specimen C3N-01381-02 (aliquot CPT0094130010_1) from CPTAC case C3N-01381, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 43.1 years (15,744 days).
Specimen C3N-01381-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fa27ede-cf64-49a7-aa21-070c9f3898b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01381-31 (Blood Derived Normal), aliquot CPT0094170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f860f71-38d0-4fb2-a702-e4826be5fa74

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, 3'UTR 2, Intron 2, RNA 1, 5'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/635 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 54/676 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- C1orf115 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs1443320732, COSV54274510; called by muse, mutect2
- FBH1 | c.1292C>G p.S431C (on ENST00000362091 / NM_178150.3; = p.S482C on NM_032807.4) | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV62982524; called by muse, mutect2
- FCGBP | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 46/964 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs747176936; called by muse, mutect2
- FZD9 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 48/521 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59989859; called by muse, mutect2
- IGF2BP1 | c.941+1G>A p.X314_splice | Splice Site (SNP) | VAF 26/285 reads (9%) | catalogued as rs751435920, COSV99288399; called by muse, mutect2
- INHBA | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 55/528 reads (10%) | catalogued as COSV54219472, COSV54224848, COSV54226824; called by muse, mutect2, varscan2
- PDE3A | c.1729C>A p.Q577K | Missense Mutation (SNP) | VAF 50/588 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62979967; called by muse, mutect2
- PRR35 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.305); catalogued as rs747782968; called by muse, mutect2
- RFTN2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs756237903; called by muse, mutect2
- TGOLN2 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 27/862 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1228071341; called by muse, mutect2
- ENPP4 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FAM163B | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- INTS7 | c.1572G>A p.W524* | Nonsense Mutation (SNP) | VAF 33/336 reads (10%) | called by muse, mutect2
- KL | c.2681A>G p.Y894C | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MECP2 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 23/514 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.291); called by muse, mutect2
- RBMX | c.59A>C p.N20T | Missense Mutation (SNP) | VAF 30/539 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- RNF217 | c.916A>G p.I306V (on ENST00000521654 / NM_001286398.2; = p.I14V on NM_152553.5) | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, varscan2
- RTEL1 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 44/570 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TARM1 | c.480G>T p.L160F (on ENST00000616041 / NM_001330650.1; = p.L152F on NM_001135686.3) | Missense Mutation (SNP) | VAF 133/879 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BAHCC1 | c.1932G>A p.L644= | Silent (SNP) | VAF 21/583 reads (4%) | called by muse, mutect2
- DCLK1 | c.84C>T p.N28= | Silent (SNP) | VAF 45/417 reads (11%) | catalogued as rs373323934; called by muse, mutect2, varscan2
- EHMT1 | c.153C>T p.D51= | Silent (SNP) | VAF 13/165 reads (8%) | catalogued as rs765396242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- GORASP2 | c.369T>G p.P123= | Silent (SNP) | VAF 37/364 reads (10%) | called by muse, mutect2, varscan2
- ISM1 | c.1308C>A p.A436= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as COSV52604606; called by muse, mutect2
- RCSD1 | c.1023G>A p.E341= | Silent (SNP) | VAF 29/250 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701504 A>G | 3'Flank (SNP) | VAF 359/1224 reads (29%) | called by muse, mutect2, varscan2
- DCHS2 | n.8299C>T | RNA (SNP) | VAF 30/341 reads (9%) | catalogued as rs771060100, COSV100600869, COSV61769423; called by muse, mutect2
- FOXP2 | c.*124C>T | 3'UTR (SNP) | VAF 46/651 reads (7%) | called by muse, mutect2
- PLA2G6 | c.2203-26C>T | Intron (SNP) | VAF 72/760 reads (9%) | catalogued as rs928536988; called by muse, mutect2
- PTK7 | c.-13T>G | 5'UTR (SNP) | VAF 34/480 reads (7%) | catalogued as rs755952591; called by muse, mutect2
- PTS | c.314+30G>A | Intron (SNP) | VAF 54/670 reads (8%) | called by muse, mutect2
- TMEM135 | c.*6204G>T | 3'UTR (SNP) | VAF 24/244 reads (10%) | catalogued as rs1376059814; called by muse, mutect2, varscan2
